TARGET case TARGET-40-NAAGJL — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bbb3ac6d-b9a8-5f26-ae1f-01aeca376d7c

Demographics
Sex at birth: female; Race: asian; Age at index: 17 years; Vital status: Dead; Days to death: 1,912 days (5.2 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.9; Tissue or organ of origin: Bone, NOS; Classification of tumor: primary; Age at diagnosis: 17.9 years (6,552 days); Year of diagnosis: 2001; Days to last follow up: 1,912 days (5.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,912.

Biospecimens (1 sample)
- Sample TARGET-40-NAAGJL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1912
- Specific tumor site: Bone NOS

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAGJL-01A-01D:
- Specimen Type: tumor DNA
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 98
- % Non Tumor Nuclei: Top from Biopsy: 2
- % Cellular Tumor: Top from Biopsy: 92
- % Normal: Top from Biopsy: 7
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 1
